Somatic mutation profile of tumor specimen TCGA-DK-A3IM-01A (aliquot TCGA-DK-A3IM-01A-11D-A20D-08) from TCGA case TCGA-DK-A3IM, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 77.0 years (28,106 days).
Specimen TCGA-DK-A3IM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b42a962-c30e-4bed-9b94-865fcf9ceb4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A3IM-10A (Blood Derived Normal), aliquot TCGA-DK-A3IM-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a5c2a52-8661-42eb-a366-1837d8f3ffdf

The open-access MAF lists 98 somatic variants for this specimen: 75 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 22, Nonsense Mutation 8, Frame Shift Del 3, Splice Site 2, Splice Region 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 20/23 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.3142A>T p.I1048F | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.023); catalogued as COSV61271401; called by muse, mutect2, varscan2
- AMZ1 | c.277C>G p.R93G | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56688322; called by muse, mutect2, varscan2
- AOC3 | c.2125A>C p.N709H | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57735015; called by muse, mutect2, varscan2
- ARID1A | c.1991C>G p.S664* | Nonsense Mutation (SNP) | VAF 88/188 reads (47%) | catalogued as COSV100250329, COSV61383603; called by muse, mutect2, varscan2
- ATMIN | c.2036C>G p.A679G | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as COSV55146979; called by muse, mutect2, varscan2
- ATP6V0A1 | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.143); catalogued as rs1344107646, COSV52876160; called by muse, mutect2, varscan2
- BRCA2 | c.2123C>A p.S708Y | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66458649; called by muse, mutect2, varscan2
- BUB1 | c.3129T>A p.H1043Q | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV57065539; called by muse, mutect2
- CCDC78 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 38/40 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs767068294, COSV52403484; called by muse, mutect2, varscan2
- CHD5 | c.210G>A p.G70= | Splice Region (SNP) | VAF 7/15 reads (47%) | catalogued as rs1292996588, COSV52420684; called by muse, mutect2, varscan2
- CLCN5 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs376001902; called by muse, mutect2
- CNN1 | c.812A>C p.K271T | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs763229153, COSV52947982; called by muse, varscan2
- CUX2 | c.4384A>G p.M1462V | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV55641049; called by muse, mutect2, varscan2
- CYP2A13 | c.17T>G p.L6R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV57839142; called by muse, mutect2, varscan2
- DNAH10 | c.7366T>C p.Y2456H (on ENST00000409039; = p.Y2395H on NM_207437.3) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as COSV68998081; called by muse, mutect2, varscan2
- ELP1 | c.1751-1G>T p.X584_splice | Splice Site (SNP) | VAF 22/76 reads (29%) | catalogued as COSV65898920; called by muse, mutect2, varscan2
- ERCC6 | c.3877G>A p.A1293T | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63392609; called by muse, mutect2, varscan2
- EXOSC9 | c.584G>A p.S195N | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV54667130; called by muse, mutect2, varscan2
- FNDC1 | c.3610C>G p.P1204A | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.097); catalogued as COSV51943678; called by muse, varscan2
- FOXQ1 | c.404C>A p.S135* | Nonsense Mutation (SNP) | VAF 38/80 reads (48%) | catalogued as COSV57258702, COSV99723361; called by muse, mutect2, varscan2
- GPR142 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs750248522, COSV59519995; called by muse, mutect2, varscan2
- GPX6 | c.104G>C p.G35A | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV62658518; called by muse, mutect2, varscan2
- HDAC11 | c.139A>C p.N47H | Missense Mutation (SNP) | VAF 63/245 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV55474079; called by muse, mutect2, varscan2
- HRNR | c.6071G>C p.G2024A | Missense Mutation (SNP) | VAF 76/383 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV64260688; called by muse, mutect2, varscan2
- KLF6 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 24/192 reads (13%) | catalogued as COSV51494463; called by muse, mutect2, varscan2
- KMT2D | c.7228C>T p.R2410* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as CM114905, COSV56416426; called by muse, mutect2, varscan2
- LMNTD1 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772520318, COSV51446210; called by muse, mutect2, varscan2
- LTBP1 | c.1109G>C p.C370S (on ENST00000404816 / NM_206943.4; = p.C44S on NM_000627.4) | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63193685; called by muse, mutect2, varscan2
- MYO5A | c.2950C>T p.R984W | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs373825708; called by muse, mutect2, varscan2
- NCOA6 | c.4274G>T p.S1425I | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV62865995; called by mutect2, varscan2
- NRG3 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV64575253, COSV64577007; called by muse, mutect2
- NXPH3 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV60872499; called by muse, mutect2, varscan2
- OCA2 | c.1228T>C p.C410R | Missense Mutation (SNP) | VAF 83/111 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV62352548; called by muse, mutect2, varscan2
- OR9Q2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs777177506, COSV61112379; called by muse, mutect2, varscan2
- PCDHB14 | c.1442G>A p.G481D | Missense Mutation (SNP) | VAF 91/292 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV53389881; called by muse, mutect2, varscan2
- PCDHB3 | c.2154G>T p.R718S | Missense Mutation (SNP) | VAF 120/246 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.121); catalogued as COSV50600327; called by muse, mutect2, varscan2
- PDZRN3 | c.2533G>A p.G845R | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as rs760912979, COSV55191241; called by muse, mutect2, varscan2
- PHF3 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 90/176 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV50328819; called by muse, mutect2, varscan2
- PIK3AP1 | c.905C>G p.T302S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); catalogued as COSV59534805, COSV59535728; called by muse, mutect2, varscan2
- PLCB3 | c.3365C>A p.T1122K | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.349); catalogued as COSV54189114, COSV54189320, COSV54190771; called by muse, mutect2, varscan2
- POGLUT3 | c.508T>C p.F170L | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV60213443; called by muse, mutect2
- POLR1D | c.167G>C p.R56P | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57256473; called by muse, mutect2, varscan2
- POTEH | c.278C>A p.T93K | Missense Mutation (SNP) | VAF 152/651 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV58885055; called by muse, varscan2
- PTGDR | c.471C>A p.S157R | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.482); catalogued as rs1202922726, COSV60094307, COSV60094646; called by muse, mutect2
- PTGFR | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 72/131 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.251); catalogued as rs374752240, COSV66115958; called by muse, mutect2, varscan2
- RERE | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1320714042, COSV61946647; called by muse, mutect2, varscan2
- RIMS1 | c.2157G>C p.M719I | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV53470783; called by muse, mutect2, varscan2
- RIMS1 | c.2158G>T p.E720* | Nonsense Mutation (SNP) | VAF 25/102 reads (25%) | catalogued as COSV99330878; called by muse, mutect2, varscan2
- RTL3 | c.1229A>T p.D410V | Missense Mutation (SNP) | VAF 59/69 reads (86%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV58185005; called by muse, mutect2, varscan2
- SH2B1 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV59465189; called by muse, mutect2, varscan2
- SH2D4B | c.1258G>A p.G420R (on ENST00000646907; = p.R345Q on NM_207372.2) | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.705); catalogued as rs750498313, COSV57892555; called by muse, mutect2, varscan2
- SLC7A1 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.206); catalogued as COSV66331244; called by muse, mutect2, varscan2
- SNX27 | c.1015C>T p.H339Y | Missense Mutation (SNP) | VAF 32/253 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.46); catalogued as COSV64327060; called by muse, mutect2, varscan2
- TAFA2 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 32/55 reads (58%) | catalogued as COSV101352965, COSV101353930, COSV69178548; called by muse, mutect2, varscan2
- TEX13A | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 155/178 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV61170034; called by muse, mutect2, varscan2
- TNFRSF25 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1415296883; called by muse, mutect2
- TRRAP | c.10249A>G p.K3417E (on ENST00000359863 / NM_001244580.1; = p.K3388E on NM_003496.3) | Missense Mutation (SNP) | VAF 91/115 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV62850332; called by muse, mutect2, varscan2
- USP25 | c.3027del p.L1009Ffs*58 | Frame Shift Del (DEL) | VAF 46/101 reads (46%) | catalogued as COSV53487627; called by mutect2, pindel, varscan2
- VPS52 | c.1489C>G p.Q497E | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.09); catalogued as COSV71403568; called by muse, mutect2, varscan2
- WWC1 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV54655195; called by muse, mutect2
- ZFX | c.853C>A p.L285I | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.109); catalogued as COSV58449136; called by muse, mutect2
- ZIC4 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.073); catalogued as rs1247040618, COSV67173124; called by muse, mutect2, varscan2
- ZNF208 | c.2516G>A p.G839D | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV68107013; called by muse, mutect2, varscan2
- ZNF445 | c.2878A>C p.S960R | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV68539320; called by muse, mutect2, varscan2
- ZNF652 | c.1187A>G p.Y396C | Missense Mutation (SNP) | VAF 130/329 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV62948096; called by muse, mutect2, varscan2
- ZP3 | c.834A>G p.I278M (on ENST00000394857 / NM_001110354.2; = p.I227M on NM_007155.6) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs1398669940; called by muse, mutect2, varscan2
- CRLF3 | c.1034_1036delinsAA p.S345* | Nonsense Mutation (DEL) | VAF 35/301 reads (12%) | called by pindel, varscan2*
- MYSM1 | c.2234C>A p.T745K | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); called by muse, mutect2
- NUDCD1 | c.913_914del p.Q305Vfs*4 | Frame Shift Del (DEL) | VAF 65/98 reads (66%) | called by mutect2, pindel, varscan2
- PARP14 | c.5080C>T p.R1694* | Nonsense Mutation (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- PPIAL4A | c.320C>T p.T107I | Missense Mutation (SNP) | VAF 93/249 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- RB1 | c.428_429del p.K143Sfs*2 | Frame Shift Del (DEL) | VAF 44/75 reads (59%) | called by mutect2, pindel, varscan2
- SLC25A30 | c.39dup p.L14Afs*7 | Frame Shift Ins (INS) | VAF 42/86 reads (49%) | called by pindel, varscan2
- SSBP3 | c.758_765+3del p.X253_splice (on ENST00000371320 / NM_145716.4; = p.X233_splice on NM_018070.5) | Splice Site (DEL) | VAF 115/452 reads (25%) | called by mutect2, pindel, varscan2
- AFF3 | c.729G>A p.Q243= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as COSV57864076; called by muse, mutect2, varscan2
- ASAH2 | c.912G>A p.P304= | Silent (SNP) | VAF 34/203 reads (17%) | catalogued as rs763316221; called by muse, mutect2, varscan2
- CADM4 | c.828C>T p.L276= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV55929491; called by muse, mutect2, varscan2
- CCAR2 | c.2001G>A p.K667= | Silent (SNP) | VAF 6/120 reads (5%) | catalogued as rs1483571011, COSV52385714; called by muse, mutect2
- FGF14 | c.33T>A p.T11= | Silent (SNP) | VAF 37/40 reads (93%) | catalogued as COSV65940525; called by muse, mutect2, varscan2
- GANAB | c.2526A>T p.G842= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as COSV55489855; called by muse, mutect2, varscan2
- IGF2R | c.6822C>T p.T2274= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as rs200731141, COSV63482316; called by muse, mutect2, varscan2
- KDM4C | c.2547G>A p.E849= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV67189519; called by muse, mutect2, varscan2
- MUC16 | c.25770G>A p.V8590= | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as COSV101199497, COSV67480661; called by muse, mutect2, varscan2
- MYLK | c.3103C>T p.L1035= | Silent (SNP) | VAF 125/263 reads (48%) | catalogued as COSV60616439; called by muse, mutect2, varscan2
- PNPLA4 | c.489C>T p.D163= | Silent (SNP) | VAF 30/34 reads (88%) | catalogued as rs150755827, COSV66853791; called by muse, mutect2, varscan2
- PTHLH | c.513G>A p.E171= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs754612994, COSV52368708; called by muse, mutect2, varscan2
- RBL1 | c.54G>T p.G18= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV100726981; called by muse, mutect2, varscan2
- RRP12 | c.1875C>T p.L625= | Silent (SNP) | VAF 38/52 reads (73%) | catalogued as COSV59669875; called by muse, mutect2, varscan2
- S1PR1 | c.1092C>T p.D364= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as rs983970449, COSV59513814; called by muse, mutect2, varscan2
- SCGB1D1 | c.195C>T p.C65= | Silent (SNP) | VAF 97/179 reads (54%) | catalogued as rs777772272; called by muse, mutect2, varscan2
- SEC16A | c.2325G>A p.S775= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs749092741, COSV51534962; called by muse, mutect2
- SPEM2 | c.453C>T p.I151= | Silent (SNP) | VAF 40/69 reads (58%) | catalogued as COSV60367351; called by muse, mutect2, varscan2
- SYT14 | c.1458T>C p.T486= | Silent (SNP) | VAF 82/97 reads (85%) | catalogued as COSV55059559; called by muse, mutect2, varscan2
- TCF4 | c.9C>T p.H3= | Silent (SNP) | VAF 45/62 reads (73%) | catalogued as rs1361892226, COSV61893856, COSV61902031; called by muse, mutect2, varscan2
- TMPRSS9 | c.582C>T p.S194= (on ENST00000648592; = p.S160= on NM_182973.2) | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as rs759274615, COSV60229767; called by muse, mutect2, varscan2
- ZNF831 | c.1323C>T p.D441= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs746195972, COSV64043127; called by mutect2, varscan2
- FLCN | c.871+38A>G | Intron (SNP) | VAF 22/231 reads (10%) | catalogued as COSV53261501; called by muse, mutect2
